Somatic mutation profile of tumor specimen MMRF_1698_1_BM_CD138pos (aliquot MMRF_1698_1_BM_CD138pos_T1_KBS5U_L06420) from MMRF case MMRF_1698, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.7 years (21,798 days).
Specimen MMRF_1698_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c41445d5-226c-418a-a53f-417a0b7d3cb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1698_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1698_1_PB_Whole_C3_KBS5U_L06467; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ec34881-ce0a-4cf1-833b-d72e7bef3a82

The open-access MAF lists 73 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 20, Silent 10, Intron 4, 5'UTR 3, 3'Flank 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 58/141 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs863224923, CM022254, CM103643; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99698625; called by muse, mutect2, varscan2
- C3orf56 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 98/141 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs370800278; called by muse, mutect2, varscan2
- CBY2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60117603; called by muse, mutect2, varscan2
- DMRTC2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs879954211; called by muse, mutect2, varscan2
- FCGR3B | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.311); catalogued as COSV54210913; called by muse, mutect2, varscan2
- GABBR2 | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1051260334; called by muse, mutect2
- GRIN2B | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.955); catalogued as rs748075089, COSV101663194, COSV74205288; called by muse, mutect2, varscan2
- IGKJ4 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 58/101 reads (57%) | PolyPhen possibly damaging (0.676); catalogued as rs551075036; called by muse, varscan2
- KCNF1 | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs762076343, COSV99705783; called by muse, mutect2, varscan2
- KRT33A | c.348+1G>A p.X116_splice | Splice Site (SNP) | VAF 45/123 reads (37%) | catalogued as rs753070534; called by muse, mutect2, varscan2
- NEK10 | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 65/234 reads (28%) | catalogued as rs1163448640, COSV55364461; called by muse, mutect2, varscan2
- OR14C36 | c.315dup p.V106Cfs*14 | Frame Shift Ins (INS) | VAF 42/127 reads (33%) | catalogued as rs761899382; called by mutect2, varscan2
- RELN | c.5968C>A p.P1990T | Missense Mutation (SNP) | VAF 94/187 reads (50%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.934); catalogued as COSV58989966; called by muse, mutect2, varscan2
- UNC45A | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754062294, COSV67793743; called by muse, mutect2, varscan2
- USH1C | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs200837155, COSV50014100; called by muse, mutect2, varscan2
- ASPG | c.281T>A p.V94D | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- BSX | c.487A>T p.M163L | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC17 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CDK12 | c.1008C>A p.F336L | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CNGA1 | c.1328C>A p.T443K | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FAF1 | c.658-2A>T p.X220_splice | Splice Site (SNP) | VAF 57/124 reads (46%) | called by muse, mutect2, varscan2
- FHOD1 | c.2989C>T p.Q997* | Nonsense Mutation (SNP) | VAF 87/168 reads (52%) | called by muse, mutect2, varscan2
- MRE11 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MTSS1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOF | c.2275G>C p.D759H | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- NDST4 | c.2419del p.W807Gfs*58 | Frame Shift Del (DEL) | VAF 32/64 reads (50%) | called by mutect2, varscan2
- PSMB4 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMC2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53RK | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DCAF4L2 | c.213C>T p.S71= | Silent (SNP) | VAF 59/187 reads (32%) | called by muse, mutect2, varscan2
- ERC2 | c.462G>A p.L154= | Silent (SNP) | VAF 67/252 reads (27%) | called by muse, mutect2, varscan2
- HCAR2 | c.915C>T p.F305= | Silent (SNP) | VAF 62/342 reads (18%) | catalogued as rs772499305, COSV61025026; called by muse, mutect2, varscan2
- HCAR3 | c.915C>T p.F305= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs748347025; called by muse, mutect2, varscan2
- IGKJ5 | c.40C>T p.*14= | Silent (SNP) | VAF 184/265 reads (69%) | catalogued as rs181580600; called by muse, varscan2
- JMY | c.1845G>A p.R615= | Silent (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- MSL3 | c.681G>A p.E227= (on ENST00000312196 / NM_078629.4; = p.E61= on NM_006800.4) | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs775364937; called by muse, mutect2, varscan2
- PHIP | c.5421C>T p.V1807= | Silent (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- PLG | c.120G>A p.Q40= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV51984471; called by muse, mutect2
- SEMA3E | c.1896G>A p.V632= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ACTL10 | c.-75C>T | 5'UTR (SNP) | VAF 7/9 reads (78%) | catalogued as rs1457393223; called by muse, mutect2, varscan2
- ADCY5 | c.1135-15326G>A | Intron (SNP) | VAF 60/254 reads (24%) | called by muse, mutect2
- ANTXR1 | c.*3822dup | 3'UTR (INS) | VAF 18/42 reads (43%) | catalogued as rs1274838241; called by mutect2, varscan2
- ARHGAP36 | c.*516A>G | 3'UTR (SNP) | VAF 78/147 reads (53%) | called by muse, mutect2, varscan2
- ARNTL2 | chr12:27421169 A>G | 3'Flank (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021491 A>C | 5'Flank (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- CLDN2 | c.*1502A>T | 3'UTR (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- CNTN3 | c.*549T>C | 3'UTR (SNP) | VAF 77/131 reads (59%) | called by muse, mutect2, varscan2
- COTL1 | c.319-99_319-81del | Intron (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- DUXA | c.-11T>C | 5'UTR (SNP) | VAF 79/113 reads (70%) | called by muse, mutect2, varscan2
- GABRB3 | c.*647G>T | 3'UTR (SNP) | VAF 71/120 reads (59%) | called by muse, mutect2, varscan2
- GABRG1 | c.*989G>A | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- GPR173 | c.*1863_*1864del | 3'UTR (DEL) | VAF 4/25 reads (16%) | catalogued as rs1491063729; called by pindel, varscan2
- GRB2 | c.*493T>G | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- GRIK3 | c.*4045G>T | 3'UTR (SNP) | VAF 58/117 reads (50%) | called by muse, mutect2, varscan2
- IP6K2 | c.203-870C>T | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- LINC02538 | n.2181G>A | RNA (SNP) | VAF 18/45 reads (40%) | catalogued as rs964807079; called by muse, mutect2, varscan2
- MAP3K8 | c.*653A>G | 3'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- NKX2-8 | c.*422G>A | 3'UTR (SNP) | VAF 60/112 reads (54%) | called by muse, mutect2, varscan2
- PAX5 | c.*4398A>G | 3'UTR (SNP) | VAF 99/220 reads (45%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*5057C>T | 3'UTR (SNP) | VAF 41/79 reads (52%) | catalogued as rs183342257; called by muse, mutect2, varscan2
- SHANK2 | c.1108-11489C>T | Intron (SNP) | VAF 12/36 reads (33%) | catalogued as rs1406890750; called by muse, mutect2, varscan2
- SLC19A3 | c.*238C>A | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- SLC5A3 | c.*3050C>T | 3'UTR (SNP) | VAF 59/92 reads (64%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*3610G>T | 3'UTR (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- SLITRK4 | chrX:143624183 C>T | 3'Flank (SNP) | VAF 41/82 reads (50%) | catalogued as rs782353038; called by muse, mutect2
- SOGA1 | c.*3703C>A | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, varscan2
- SORL1 | c.*2342T>C | 3'UTR (SNP) | VAF 47/72 reads (65%) | called by muse, mutect2, varscan2
- SP140 | c.-31A>G | 5'UTR (SNP) | VAF 61/140 reads (44%) | catalogued as rs1330958598; called by muse, mutect2, varscan2
- TCEAL3 | c.*169G>C | 3'UTR (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- TMEM155 | c.*832A>G | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- TP53BP1 | chr15:43404602 A>C | 3'Flank (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
